Somatic mutation profile of tumor specimen TCGA-CH-5761-01A (aliquot TCGA-CH-5761-01A-11D-1576-08) from TCGA case TCGA-CH-5761, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.4 years (22,433 days).
Specimen TCGA-CH-5761-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ae9f9e-97f4-499a-940f-0e3614f946c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5761-11A (Solid Tissue Normal), aliquot TCGA-CH-5761-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10fa1709-5067-49df-ba5a-cfd66c696802

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADAC | c.1151G>T p.S384I | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV51761162; called by muse, mutect2, varscan2
- ADGRL3 | c.904C>T p.R302W (on ENST00000506720 / NM_001322402.2; = p.R234W on NM_015236.6) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs548241584, COSV72272902; called by muse, mutect2, varscan2
- AXL | c.2257G>A p.V753M (on ENST00000301178 / NM_021913.5; = p.V744M on NM_001699.6) | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372169583, COSV56572090; called by muse, mutect2, varscan2
- BTK | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 132/205 reads (64%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV58117893, COSV58121329; called by muse, mutect2, varscan2
- CFH | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62778671; called by muse, mutect2
- CHD1L | c.537G>T p.L179F | Missense Mutation (SNP) | VAF 171/511 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100787387, COSV63615247; called by muse, mutect2, varscan2
- CLGN | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.914); catalogued as COSV57776306; called by muse, mutect2, varscan2
- CNTN4 | c.48C>A p.C16* | Nonsense Mutation (SNP) | VAF 72/192 reads (38%) | catalogued as COSV68589756; called by muse, mutect2, varscan2
- DEK | c.232T>G p.F78V | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV55239547; called by muse, mutect2, varscan2
- DPYD | c.2683A>G p.I895V | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64612546; called by muse, mutect2, varscan2
- DUS3L | c.1130G>A p.C377Y | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57833465; called by muse, mutect2, varscan2
- EFCAB7 | c.742A>C p.T248P | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as COSV64315269; called by muse, mutect2, varscan2
- FGA | c.1387A>C p.K463Q | Missense Mutation (SNP) | VAF 149/484 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57400214; called by muse, mutect2, varscan2
- FMNL2 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.037); catalogued as COSV56503237; called by muse, mutect2, varscan2
- GPR174 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 140/205 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV52134123; called by muse, mutect2, varscan2
- HARBI1 | c.825T>G p.D275E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV58706764; called by muse, mutect2, varscan2
- INTS1 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs377546188; called by muse, mutect2, varscan2
- IRAK2 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs374087042, COSV56528869, COSV56535280; called by muse, mutect2, varscan2
- MYO1E | c.41A>C p.H14P | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.514); catalogued as COSV55694367; called by muse, mutect2, varscan2
- PATE2 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs748478418, COSV62069683; called by muse, mutect2, varscan2
- PDIA6 | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV55353144; called by muse, mutect2, varscan2
- PNMA5 | c.1192A>C p.S398R | Missense Mutation (SNP) | VAF 79/125 reads (63%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62626206; called by muse, mutect2, varscan2
- PPP2R5E | c.934A>G p.K312E | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV61744016; called by muse, mutect2, varscan2
- PRM3 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as rs756977444, COSV54113814; called by mutect2, varscan2
- RAB3GAP1 | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV51487863; called by muse, mutect2, varscan2
- RBM5 | c.1278G>A p.P426= | Splice Region (SNP) | VAF 95/330 reads (29%) | catalogued as rs1385370839, COSV61738848; called by muse, mutect2, varscan2
- SERPINB2 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs376346521, COSV55092920; called by muse, mutect2, varscan2
- SLC5A8 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs199610556; called by muse, mutect2, varscan2
- SPATA5L1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.173); catalogued as COSV59745510; called by muse, varscan2
- SRMS | c.1188G>C p.E396D | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53918347; called by muse, mutect2, varscan2
- TARBP1 | c.3555G>A p.Q1185= | Splice Region (SNP) | VAF 50/151 reads (33%) | catalogued as COSV50202026; called by muse, mutect2, varscan2
- TFAM | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs553009666, COSV65876066; called by muse, mutect2, varscan2
- TPRN | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs758323082, COSV58808920; called by muse, mutect2, varscan2
- U2SURP | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs1186177225, COSV67530201; called by muse, mutect2, varscan2
- ZIC1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV51550276; called by muse, mutect2, varscan2
- DVL2 | c.1099dup p.R367Pfs*3 | Frame Shift Ins (INS) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- GAPVD1 | c.4233del p.N1412Mfs*19 (on ENST00000394104; = p.N1421Mfs*19 on NM_015635.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/287 reads (29%) | called by mutect2, pindel, varscan2
- MLLT10 | c.2413del p.T805Lfs*5 (on ENST00000307729 / NM_001195626.3; = p.T821Lfs*5 on NM_004641.3) | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- TBC1D8B | c.3296_3297insT p.I1100Hfs*18 | Frame Shift Ins (INS) | VAF 90/142 reads (63%) | called by mutect2, varscan2
- ERBB4 | c.3402G>T p.V1134= | Silent (SNP) | VAF 63/194 reads (32%) | catalogued as COSV61518005; called by muse, mutect2, varscan2
- FZD4 | c.774C>T p.L258= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV72294678; called by muse, mutect2, varscan2
- GPT2 | c.633C>T p.I211= | Silent (SNP) | VAF 132/222 reads (59%) | catalogued as rs760014043, COSV60838715; called by muse, varscan2
- HOXB2 | c.120G>C p.S40= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV57486294, COSV57488131; called by muse, mutect2
- KCND2 | c.1359C>A p.L453= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV58600525; called by muse, mutect2, varscan2
- KCNK4 | c.723C>T p.L241= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs143683020; called by muse, mutect2, varscan2
- MGAM | c.3202C>T p.L1068= | Silent (SNP) | VAF 130/223 reads (58%) | catalogued as rs1563171732, COSV72075673; called by muse, mutect2, varscan2
- PPAT | c.369C>T p.G123= | Silent (SNP) | VAF 91/284 reads (32%) | catalogued as rs780665582, COSV51706386; called by muse, mutect2, varscan2
- TRANK1 | c.6810G>A p.L2270= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as COSV57162483; called by muse, mutect2, varscan2
- ZAN | c.2547A>G p.K849= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV61815268; called by muse, mutect2, varscan2
- MIR376C | n.9G>T | RNA (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
